Gene-level copy-number profile of tumor specimen TARGET-51-PAJMFS-01A from TARGET case TARGET-51-PAJMFS, project TARGET-CCSK (Clear Cell Sarcoma of the Kidney). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell sarcoma of kidney; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 2.6 years (949 days).
Specimen TARGET-51-PAJMFS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-CCSK.dc4856e1-f0c0-5ef8-82f7-bfe7d94dcbfd.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-51-PAJMFS-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 351 have no estimate.
https://portal.gdc.cancer.gov/files/fdd15d3f-eff8-46a9-bda9-10d2e1f847fb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,382; copy number 1: 113; copy number 2: 57,777.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:68,693,804–68,694,081, 1 gene: RN7SL761P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 113. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
